Somatic mutation profile of tumor specimen C3N-08883-01 (aliquot CPT0473210007) from CPTAC case C3N-08883, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.0 years (23,359 days).
Specimen C3N-08883-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4e765ef-8ed1-4446-b9d0-211c55691357.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-08883-31 (Blood Derived Normal), aliquot CPT0473300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d3c310e-1b93-4d76-8927-186c1c6eb35f

The open-access MAF lists 118 somatic variants for this specimen: 87 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 27, Frame Shift Del 3, Nonsense Mutation 3, Intron 2, Splice Site 1, 5'Flank 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC4A1 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs121912744, CM971387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 27/215 reads (13%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AK7 | c.2120C>T p.P707L | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50883586; called by muse, mutect2, varscan2
- ALDH8A1 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 66/401 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs747404906, COSV55642213; called by muse, mutect2, varscan2
- ASXL3 | c.5419G>A p.G1807S | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.68); catalogued as rs781048573, COSV52464324; called by muse, mutect2
- C12orf4 | c.1472C>G p.A491G | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866573238, COSV99712667; called by muse, mutect2
- CADM2 | c.866C>T p.T289M (on ENST00000407528 / NM_001167674.2; = p.T291M on NM_153184.4) | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67369439; called by muse, mutect2
- CALB2 | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56939129; called by muse, mutect2
- CLUH | c.3805G>A p.A1269T (on ENST00000435359; = p.A1308T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/464 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1239497692; called by muse, mutect2
- CPQ | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1233564031; called by muse, mutect2, varscan2
- CSMD1 | c.7855C>T p.R2619* (on ENST00000520002; = p.R2618* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 22/184 reads (12%) | catalogued as rs766376387, COSV59284438, COSV59393692; called by muse, mutect2, varscan2
- EVC | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs369800853, COSV99382162; called by muse, mutect2
- GLI3 | c.4105G>A p.G1369S | Missense Mutation (SNP) | VAF 40/405 reads (10%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1446295282, COSV67887366; called by muse, mutect2
- KCNB2 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 52/550 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.595); catalogued as rs750005116, COSV73049937, COSV73050498; called by muse, mutect2
- KCNT1 | c.1093G>A p.D365N (on ENST00000488444; = p.D384N on NM_020822.3) | Missense Mutation (SNP) | VAF 31/396 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs762752381, COSV53702560; ClinVar: uncertain significance; called by muse, mutect2
- MYH11 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 46/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160451543, COSV100258169; called by muse, mutect2, varscan2
- NCAN | c.3904C>T p.R1302C | Missense Mutation (SNP) | VAF 48/630 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs754820835; called by muse, mutect2
- NDUFA11 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757263590, COSV99398784; called by muse, varscan2
- NPAP1 | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201894790, COSV61505775; called by muse, mutect2
- ODF1 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 79/444 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV53434096; called by muse, mutect2, varscan2
- OGDH | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs371818366; called by muse, mutect2
- PCDHAC1 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs782199565, COSV99165692; called by muse, mutect2, varscan2
- PGBD5 | c.893G>A p.R298H (on ENST00000525115; = p.R367H on NM_001258311.2) | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs771554152, COSV58413192; called by muse, mutect2
- PLEC | c.13693G>A p.V4565M (on ENST00000322810 / NM_201380.4; = p.V4455M on NM_000445.5) | Missense Mutation (SNP) | VAF 53/582 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs781960986, COSV59680778; ClinVar: uncertain significance; called by muse, mutect2
- PXDNL | c.3254T>C p.L1085P | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1189714745; called by muse, mutect2
- RBPMS2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 40/379 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs753180915; called by muse, mutect2, varscan2
- RPRD2 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs748567967; called by muse, mutect2, varscan2
- SAFB | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99413269; called by muse, mutect2, varscan2
- SMC3 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs377731006; called by muse, mutect2
- STRC | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 41/713 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.277); catalogued as rs757152351; ClinVar: uncertain significance; called by muse, mutect2
- TENT5C | c.959G>C p.C320S | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65616293; called by muse, mutect2
- TMPRSS15 | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as rs778496939, COSV53034807; called by muse, mutect2
- TPO | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 35/518 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV100219602; called by muse, mutect2
- TRUB1 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs531711499, COSV53928917; called by muse, mutect2
- USP19 | c.3538C>T p.R1180C | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778546706, COSV101296116; called by muse, mutect2, varscan2
- AC100868.1 | c.1937C>A p.A646E | Missense Mutation (SNP) | VAF 49/477 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ADCY8 | c.2045A>C p.K682T | Missense Mutation (SNP) | VAF 80/462 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY8 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 16/433 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- ADGRL3 | c.2789C>A p.A930E (on ENST00000506720 / NM_001322402.2; = p.A862E on NM_015236.6) | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ALCAM | c.194C>G p.P65R | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ANKRD30A | c.3084-1G>A p.X1028_splice (on ENST00000611781; = p.X972_splice on NM_052997.2) | Splice Site (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- ANO4 | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 15/321 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2
- B3GAT1 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 52/496 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- C12orf40 | c.1346A>T p.E449V | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- CCDC141 | c.244T>C p.W82R | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CFAP54 | c.4387A>C p.S1463R | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- COL25A1 | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 23/335 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSPP1 | c.806A>C p.Q269P (on ENST00000676605; = p.Q228P on NM_024790.6) | Missense Mutation (SNP) | VAF 32/397 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- DCLK1 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 42/792 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); called by muse, mutect2
- DHX9 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2
- EFHB | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 42/433 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- EGR4 | c.653C>A p.P218H (on ENST00000545030; = p.P115H on NM_001965.4) | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FAM160A2 | c.769T>G p.F257V | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- FBN2 | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2
- FOXP2 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- FREM2 | c.4959_4960del p.N1653Kfs*9 | Frame Shift Del (DEL) | VAF 38/417 reads (9%) | called by mutect2, pindel
- GBP7 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 29/331 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- GPSM2 | c.2009C>A p.A670D | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); called by muse, mutect2
- IL1RAPL1 | c.240del p.G81Vfs*9 | Frame Shift Del (DEL) | VAF 40/256 reads (16%) | called by mutect2, pindel, varscan2
- KLF14 | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.726); called by muse, mutect2
- L3MBTL1 | c.2003G>T p.C668F (on ENST00000418998 / NM_001377303.1; = p.C578F on NM_015478.7) | Missense Mutation (SNP) | VAF 54/532 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2
- MARCHF11 | c.478G>C p.G160R | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- NEMP2 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NID1 | c.1821C>A p.Y607* | Nonsense Mutation (SNP) | VAF 10/329 reads (3%) | called by muse, mutect2
- OBSCN | c.5823C>G p.S1941R | Missense Mutation (SNP) | VAF 46/418 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- OR13C2 | c.927C>A p.H309Q | Missense Mutation (SNP) | VAF 27/327 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- PCDH18 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.266); called by muse, mutect2
- PNLIPRP3 | c.763T>G p.L255V | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.18); called by muse, mutect2
- RASGRP3 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- RPS6KC1 | c.2698del p.Y900Tfs*16 | Frame Shift Del (DEL) | VAF 40/373 reads (11%) | called by mutect2, pindel, varscan2
- SAMSN1 | c.873C>A p.D291E (on ENST00000647101; = p.D63E on NM_001256370.1) | Missense Mutation (SNP) | VAF 35/380 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2
- SLC14A1 | c.945T>C p.C315= | Splice Region (SNP) | VAF 25/218 reads (11%) | called by muse, mutect2, varscan2
- SMARCA5 | c.1647C>A p.N549K | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.141); called by muse, mutect2
- SPAG17 | c.5757A>T p.L1919F | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- SYNE1 | c.4495A>G p.S1499G (on ENST00000367255 / NM_182961.4; = p.S1506G on NM_033071.3) | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- TATDN1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS11F | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 37/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNS2 | c.49A>G p.R17G | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2
- TRDMT1 | c.895A>C p.S299R | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPS1 | c.2869G>T p.A957S (on ENST00000220888 / NM_001330599.2; = p.A970S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TTN | c.98636A>C p.K32879T (on ENST00000591111; = p.K25455T on NM_003319.4) | Missense Mutation (SNP) | VAF 40/382 reads (10%) | PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TUT4 | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TYK2 | c.3187A>C p.S1063R | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS37D | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- VWDE | c.3956G>C p.G1319A | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- XIRP2 | c.1379A>G p.D460G (on ENST00000628543; = p.D635G on NM_152381.6) | Missense Mutation (SNP) | VAF 19/325 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- ZMYND10 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); called by muse, mutect2
- CCDC141 | c.3522A>G p.E1174= | Silent (SNP) | VAF 28/299 reads (9%) | called by muse, mutect2, varscan2
- CDH11 | c.27C>T p.A9= | Silent (SNP) | VAF 31/317 reads (10%) | catalogued as rs200930494, COSV51781373; called by muse, mutect2
- CROCC2 | c.3531G>A p.A1177= | Silent (SNP) | VAF 40/371 reads (11%) | catalogued as rs960259049, COSV69132348; called by muse, mutect2, varscan2
- FAT1 | c.4755G>T p.T1585= | Silent (SNP) | VAF 28/315 reads (9%) | called by muse, mutect2
- FOXB2 | c.741C>T p.Y247= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs764872239, COSV65022377; called by muse, mutect2
- GPR179 | c.3567G>A p.G1189= (on ENST00000621958; = p.G1188= on NM_001004334.4) | Silent (SNP) | VAF 35/665 reads (5%) | called by muse, mutect2
- IER5L | c.138C>A p.L46= | Silent (SNP) | VAF 45/442 reads (10%) | called by muse, mutect2
- KCNJ2 | c.273T>C p.A91= | Silent (SNP) | VAF 40/482 reads (8%) | catalogued as COSV54660988, COSV54661803; called by muse, mutect2
- KRT81 | c.117C>A p.R39= | Silent (SNP) | VAF 37/382 reads (10%) | called by muse, mutect2, varscan2
- LRRK2 | c.4141A>C p.R1381= | Silent (SNP) | VAF 27/450 reads (6%) | catalogued as rs1173861444; called by muse, mutect2
- MMP13 | c.969G>A p.T323= | Silent (SNP) | VAF 14/353 reads (4%) | catalogued as rs782597212, COSV52824858; called by muse, mutect2
- MYF5 | c.708C>T p.T236= | Silent (SNP) | VAF 28/354 reads (8%) | catalogued as rs565591443; called by muse, mutect2
- OR5M10 | c.777C>T p.Y259= | Silent (SNP) | VAF 25/278 reads (9%) | catalogued as rs199665621; called by muse, mutect2, varscan2
- OTUD6A | c.855G>A p.P285= | Silent (SNP) | VAF 47/177 reads (27%) | catalogued as rs748580751; called by muse, mutect2, varscan2
- PCDHB3 | c.1041G>C p.L347= | Silent (SNP) | VAF 34/401 reads (8%) | catalogued as COSV50564076; called by muse, mutect2
- PDYN | c.72G>A p.S24= | Silent (SNP) | VAF 23/300 reads (8%) | catalogued as rs745951521, COSV54100997; ClinVar: benign; called by muse, mutect2
- PDZRN3 | c.1983T>G p.P661= | Silent (SNP) | VAF 44/353 reads (12%) | called by muse, mutect2, varscan2
- PLPP5 | c.156G>A p.A52= | Silent (SNP) | VAF 41/288 reads (14%) | catalogued as rs1369941461; called by muse, mutect2, varscan2
- PYGB | c.1062G>C p.L354= | Silent (SNP) | VAF 30/316 reads (9%) | called by muse, mutect2
- SDCBP2 | c.555G>A p.R185= (on ENST00000339987 / NM_001199784.1; = p.R100= on NM_015685.5) | Silent (SNP) | VAF 25/303 reads (8%) | called by muse, mutect2
- SETBP1 | c.4392C>T p.F1464= | Silent (SNP) | VAF 49/412 reads (12%) | catalogued as COSV56318043; called by muse, mutect2, varscan2
- SNX27 | c.1506C>A p.I502= | Silent (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
- ST6GALNAC1 | c.1242C>T p.T414= | Silent (SNP) | VAF 42/498 reads (8%) | catalogued as rs761042317; called by muse, mutect2
- TNXB | c.4665G>A p.A1555= (on ENST00000647633; = p.A1308= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/373 reads (8%) | catalogued as rs745464565, COSV64475095; called by muse, mutect2
- TRPC4 | c.96A>G p.S32= | Silent (SNP) | VAF 34/530 reads (6%) | catalogued as rs1566168048; called by muse, mutect2
- UCKL1 | c.1344C>T p.H448= | Silent (SNP) | VAF 33/297 reads (11%) | catalogued as rs1479923839, COSV62402768, COSV62403362; called by muse, mutect2, varscan2
- ZNF182 | c.804A>G p.G268= | Silent (SNP) | VAF 44/222 reads (20%) | catalogued as COSV100527212; called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084999 G>A | 5'Flank (SNP) | VAF 24/306 reads (8%) | catalogued as rs759720335; called by muse, mutect2
- FBLIM1 | c.890+145G>T | Intron (SNP) | VAF 11/90 reads (12%) | catalogued as rs1200564426; called by muse, mutect2, varscan2
- LRRFIP1 | c.747+1283A>G | Intron (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- Z99774.2 | chr22:26676139 A>G | 3'Flank (SNP) | VAF 27/213 reads (13%) | called by muse, mutect2, varscan2
